Somatic mutation profile of tumor specimen MP2PRT-PAVXJU-TBP1-A (aliquot MP2PRT-PAVXJU-TBP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVXJU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,014 days).
Specimen MP2PRT-PAVXJU-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c98a52e1-449a-42bb-a9f4-5b4a661fa965.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXJU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXJU-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eabe611b-dc58-4929-811a-905d10d2186b

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B3 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 81/337 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762490848, COSV59544974; called by muse, mutect2, varscan2
- CCDC168 | c.12220G>A p.E4074K | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as COSV59422547; called by muse, mutect2
- OR10W1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 82/368 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs544577916, COSV67720315, COSV67720527, COSV67720543; called by muse, mutect2, varscan2
- TBX20 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68785610, COSV68785803; called by muse, mutect2
- APOB | c.13204G>C p.E4402Q | Missense Mutation (SNP) | VAF 25/389 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, mutect2
- C3 | c.2986G>A p.D996N | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- KIAA1671 | c.2570G>T p.W857L | Missense Mutation (SNP) | VAF 84/607 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A2 | c.336C>T p.I112= | Silent (SNP) | VAF 120/489 reads (25%) | catalogued as rs200256912; called by muse, mutect2, varscan2
- FOXRED2 | c.2001C>G p.P667= | Silent (SNP) | VAF 28/528 reads (5%) | catalogued as rs376517238; called by muse, mutect2
- NGDN | c.528G>A p.L176= | Silent (SNP) | VAF 60/251 reads (24%) | called by muse, mutect2, varscan2
- THBS1 | c.2010C>T p.S670= | Silent (SNP) | VAF 103/426 reads (24%) | catalogued as rs769911853; called by muse, mutect2, varscan2
